Somatic mutation profile of tumor specimen TCGA-XF-AAMJ-01A (aliquot TCGA-XF-AAMJ-01A-11D-A42E-08) from TCGA case TCGA-XF-AAMJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 70.7 years (25,838 days).
Specimen TCGA-XF-AAMJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee41743f-c6e6-45ba-a773-7896c93efbb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAMJ-10A (Blood Derived Normal), aliquot TCGA-XF-AAMJ-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a440af6-d3e4-4f65-a5e8-7c1788048829

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 26, Silent 7, Frame Shift Del 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTSA | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137854547, CM961143, COSV99509770; ClinVar: pathogenic; called by mutect2, varscan2
- ACOX2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201115263, COSV57147767; called by muse, mutect2, varscan2
- ADAM10 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV53051272; called by muse, mutect2, varscan2
- ALMS1 | c.10680G>T p.M3560I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100041885; called by muse, mutect2
- ANGPT1 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52438655; called by muse, mutect2
- ANK2 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs747860838, COSV52158487; called by muse, mutect2, varscan2
- ARSH | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs140056528, COSV101139997, COSV66962872; called by muse, mutect2, varscan2
- CACNA1E | c.4282G>T p.E1428* | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | catalogued as COSV100701828; called by muse, mutect2
- CHD8 | c.3274C>T p.R1092C (on ENST00000646647 / NM_001170629.2; = p.R813C on NM_020920.4) | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439223724, COSV67870139; called by muse, mutect2
- CHRNA2 | c.1513C>T p.L505F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53557548; called by muse, mutect2, varscan2
- CTNNA2 | c.2265G>A p.M755I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV100559124, COSV58149835; called by muse, mutect2, varscan2
- CYLC2 | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs1270241640, COSV66336982, COSV66337374, COSV66339898; called by muse, mutect2, varscan2
- DNAH5 | c.11534G>A p.R3845H | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.608); catalogued as rs1181350575, COSV54210853; called by muse, mutect2, varscan2
- DNAJC4 | c.462_465del p.Q155Cfs*23 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | catalogued as rs753541691; called by pindel, varscan2
- DSEL | c.3320C>T p.S1107F | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.82); catalogued as COSV59491114; called by muse, mutect2, varscan2
- ETAA1 | c.809G>A p.S270N | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV55472839; called by muse, mutect2, varscan2
- GALNT11 | c.953C>A p.A318E | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.309); catalogued as COSV57425676; called by muse, mutect2, varscan2
- H2BC12 | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.414); catalogued as COSV63616914; called by muse, mutect2
- HOXA13 | c.1063A>C p.I355L | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); catalogued as COSV56083314; called by muse, mutect2
- NSD1 | c.1727dup p.N576Kfs*8 | Frame Shift Ins (INS) | VAF 10/63 reads (16%) | catalogued as rs1299932363; called by mutect2, pindel, varscan2
- OR4D10 | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753106840, COSV73260016, COSV73260022; called by muse, mutect2, varscan2
- PCDHA5 | c.1288G>T p.G430C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV65351865; called by muse, mutect2, varscan2
- PCDHB6 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs904708904, COSV50695334; called by muse, mutect2, varscan2
- RBM4 | c.1045C>G p.R349G | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV59518691; called by mutect2, varscan2
- SALL1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.278); catalogued as rs1397551246, COSV51756703; called by muse, mutect2
- TNP2 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs774953108, COSV57129135; called by muse, mutect2, varscan2
- TP53 | c.105_106del p.L35Ffs*7 | Frame Shift Del (DEL) | VAF 27/141 reads (19%) | catalogued as COSV52983787; called by mutect2, pindel, varscan2
- ZBTB49 | c.1943C>G p.S648C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61924926; called by muse, mutect2, varscan2
- ZNF106 | c.3053G>A p.R1018Q | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV55516243; called by muse, mutect2, varscan2
- ZNF425 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.215); catalogued as rs1165656351, COSV65201205; called by muse, mutect2, varscan2
- AZGP1 | c.393C>T p.S131= | Silent (SNP) | VAF 60/248 reads (24%) | catalogued as rs777569319, COSV52796934; called by muse, mutect2, varscan2
- CAND1 | c.2907G>A p.R969= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV101607308; called by muse, mutect2
- CENPO | c.528C>T p.F176= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV53167046, COSV53168178; called by muse, mutect2, varscan2
- INF2 | c.624C>T p.P208= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs750610272, COSV53032143, COSV53035900; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRTM1 | c.273C>A p.L91= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV54440635; called by muse, mutect2
- NT5E | c.714C>G p.V238= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV57628208; called by muse, mutect2, varscan2
- ZNF829 | c.534T>C p.H178= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV66986189; called by muse, mutect2, varscan2
